Somatic mutation profile of tumor specimen TCGA-J4-8198-01A (aliquot TCGA-J4-8198-01A-11D-2260-08) from TCGA case TCGA-J4-8198, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.1 years (17,935 days).
Specimen TCGA-J4-8198-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60ba832e-b6eb-4622-8663-33eebb91d469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-8198-10A (Blood Derived Normal), aliquot TCGA-J4-8198-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a431d73-6875-42c5-ac04-ca0aab961ef8

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs104894286, CM981696; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP5F1A | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.076); catalogued as rs776829339, COSV56361146; called by muse, mutect2, varscan2
- BDKRB1 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53706703; called by muse, mutect2, varscan2
- BIRC2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV57162450; called by muse, mutect2, varscan2
- C19orf44 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55613335; called by muse, mutect2, varscan2
- C6 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs545743707, COSV54713718; called by muse, mutect2, varscan2
- EPB41L3 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as COSV59446834, COSV59461112; called by muse, mutect2, varscan2
- FMN2 | c.3310G>A p.G1104R | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as COSV60415892; called by muse, varscan2
- GTF2E2 | c.678T>G p.D226E | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV63478775; called by muse, mutect2, varscan2
- KRT25 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1333733353, COSV56443482, COSV56446351; called by muse, mutect2, varscan2
- LAMA4 | c.1673C>T p.A558V (on ENST00000230538 / NM_001105206.3; = p.A551V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs137893207, COSV57896467, COSV57897455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN2 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1405384247, COSV57831110; called by muse, mutect2, varscan2
- MED13 | c.3105A>T p.K1035N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67265356; called by muse, mutect2, varscan2
- MYO15A | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52761009; called by muse, mutect2, varscan2
- NLRP12 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV60750774; called by muse, mutect2, varscan2
- POLD3 | c.18T>G p.Y6* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55244267; called by muse, mutect2, varscan2
- RIF1 | c.6008A>C p.N2003T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV54620500; called by muse, mutect2, varscan2
- RSPH6A | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV55573735; called by muse, mutect2, varscan2
- SLC3A1 | c.1782C>G p.I594M | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV53218020; called by muse, mutect2, varscan2
- HELQ | c.336_343del p.S113* | Frame Shift Del (DEL) | VAF 43/154 reads (28%) | called by mutect2, pindel, varscan2
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 46/195 reads (24%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.2922G>A p.V974= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV70498164; called by muse, mutect2, varscan2
- IARS2 | c.531T>C p.A177= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV56961838; called by muse, mutect2, varscan2
- ISLR | c.66C>T p.P22= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV51434478; called by muse, mutect2, varscan2
- ZNF433 | c.786A>G p.A262= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs963384527, COSV61399869; called by muse, mutect2, varscan2
